Somatic mutation profile of tumor specimen 0DT7X6 from CCDI case PBCJHZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 14.0 years (5,104 days).
Specimen 0DT7X6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5da66f77-f699-42d1-94e8-d44f7763afbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT7WU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b2c9ff1-23f0-46a7-a4e4-6668d91c4841

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Splice Site 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KALRN | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 403/911 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53751817, COSV99564939; called by muse, mutect2, varscan2
- LARS1 | c.2297G>A p.R766H (on ENST00000394434 / NM_020117.11; = p.R739H on NM_016460.3) | Missense Mutation (SNP) | VAF 784/1635 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs779132226; called by muse, mutect2, varscan2
- NTRK2 | c.2195C>T p.T732M (on ENST00000323115 / NM_001369534.1; = p.T748M on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 708/1469 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367769334; called by muse, mutect2, varscan2
- PDCD1LG2 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 562/1202 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270755529, COSV101173054; called by muse, mutect2, varscan2
- PRR23A | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 378/824 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV67215313; called by muse, mutect2, varscan2
- PTCHD4 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 403/891 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as rs758042146, COSV59778781; called by muse, mutect2, varscan2
- SYDE1 | c.1915G>A p.G639S | Missense Mutation (SNP) | VAF 456/939 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs774042409, COSV54617890; called by muse, mutect2, varscan2
- CDK19 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 703/1690 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CTTNBP2 | c.4447+1G>A p.X1483_splice | Splice Site (SNP) | VAF 371/889 reads (42%) | called by muse, mutect2, varscan2
- DDX3X | c.1514A>G p.D505G (on ENST00000399959; = p.D506G on NM_001356.5) | Missense Mutation (SNP) | VAF 622/1494 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by mutect2, varscan2
- KLHL22 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 414/879 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- PTCH1 | c.1776dup p.P593Sfs*34 | Frame Shift Ins (INS) | VAF 667/1783 reads (37%) | called by mutect2, pindel, varscan2
- SKIDA1 | c.1844C>G p.T615R | Missense Mutation (SNP) | VAF 693/1688 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- KHDC1L | c.36G>A p.P12= | Silent (SNP) | VAF 54/1190 reads (5%) | catalogued as COSV64893280; called by muse, mutect2
- PIK3CG | c.2652C>T p.D884= | Silent (SNP) | VAF 618/1535 reads (40%) | catalogued as rs755002463, COSV63248548; called by muse, mutect2, varscan2
- PLA2G4A | c.1254G>A p.E418= | Silent (SNP) | VAF 513/1215 reads (42%) | catalogued as COSV66552420; called by muse, mutect2, varscan2
- TTC34 | c.2028C>T p.I676= | Silent (SNP) | VAF 403/978 reads (41%) | catalogued as rs547214393; called by muse, mutect2, varscan2
- FRRS1L | c.*62dup | 3'UTR (INS) | VAF 177/425 reads (42%) | catalogued as rs1338824302; called by mutect2, pindel, varscan2
